Surgical pathology report (de-identified scan), TCGA case TCGA-86-8359, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Asterand, specimen TCGA-86-8359-01A (Primary Tumor).

[page 1 of 4]
[REDACTED]

[REDACTED]

[REDACTED]		Case ID	Gross Description
[REDACTED]		[REDACTED]	Lung of increased volume with free lobar bronchus; the lower lobar bronchus is free on the proximal portion and obstructed in the distal portion by a tumoral process which occupies approximately 2 thirds of the lower lobe; on section, a tumoral structure of 12/10 cm; the tumor is well-limited, white, with small areas of necrosis and hemorrhage, with mucous secretions on surface.

[page 2 of 4]
Microscopic Description	Diagnosis Details
TUMOR FRAGMENT: Bronchopulmonary neoplasm of differentiated muciparous adenocarcinoma type, formed of tubular-papillary structures, covered by a layered cylindrical epithelium, with moderate cellular pleomorphism and rare mitoses. Some of the cells are vacuolated, with intracellular necrotic content and inside the glandular spaces. The tumoral stroma with fibrous structure and numerous vessels with stasis and moderate diffuse lymphocytic infiltrate. PULMONARY PARENCHYMA: Diffuse interstitial moderate fibrosis, stasis and accumulations of macrophages in the alveoli. Small hotbeds of emphysema with subpleural localization. LYMPH NODE STATION VI: Mediastinal tissue with lymph node with sinus histiocytosis and stasis. Without neoplastic infiltrates. LYMPH NODE STATION V: Stasis, follicular hyperplasia and sinus histiocytosis with numerous alveolar macrophages. Without neoplastic infiltrates. PHRENIC CHAIN LYMPH NODE: Fibrosis and sinus histiocytosis. Without neoplastic infiltrates. TRIANGULAR LIGAMENT LYMPH NODE: Reactive follicular hyperplasia and sinus histiocytosis, with numerous alveolar macrophages. PARAESOPHAGEAL LYMPH NODE: Lymph node with metastasis of the muciparous tubular-papillary adenocarcinoma. LYMPH NODE STATION IV:	

[page 3 of 4]
Comments	Formatted Path Report
	LUNG TISSUE CHECKLIST Specimen type: Lobectomy Tumor site: Lung Tumor size: 12 x 10 cm Histologic type: Adenocarcinoma Histologic grade: Moderately differentiated Tumor extent: Not specified Other tumor nodules: Not specified Lymph nodes: 1/7 positive for metastasis (St.5,6,10,7,6 0/6, Paraesophageal 1/1) Lymphatic invasion: Present Venous invasion: Present Margins: Uninvolved Evidence of neo-adjuvant treatment: Not specified Additional pathologic findings: Not specified Comments: Left- lower with obstruction of distal lobular bronchus

[page 4 of 4]
	ID	Excision Date	Laterality
			Left-lower

Source: NCI Genomic Data Commons file 803fbfea-a909-4055-9997-fa94c44de070 (TCGA-86-8359.7525ADB2-550A-4D65-BEED-5FB0FEF0B36D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).